Somatic mutation profile of tumor specimen TCGA-AB-2929-03A (aliquot TCGA-AB-2929-03A-01W-0732-08) from TCGA case TCGA-AB-2929, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.3 years (26,054 days).
Specimen TCGA-AB-2929-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d29b9d72-6905-4a7a-8f41-9f39a680c105.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2929-11A (Solid Tissue Normal), aliquot TCGA-AB-2929-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/136ee151-96ea-4048-bd9c-0200b85e9638

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRPF39 | c.208C>T p.L70= | Silent (SNP) | VAF 6/164 reads (4%) | catalogued as COSV100866050; called by muse, mutect2
